Somatic mutation profile of tumor specimen 0DQZ4H from CCDI case PBCFUK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.1 years (1,860 days).
Specimen 0DQZ4H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33866265-e3aa-4b33-bd51-e8b5d2818e2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f93c872-0f80-4e08-b88f-9ebceb86365a

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 3, Intron 2, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 111/219 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 142/295 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- AKT3 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV55609219; called by muse, mutect2, varscan2
- CEMIP | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 28/264 reads (11%) | catalogued as rs771084010; called by muse, mutect2, varscan2
- SLC14A2 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs776377373, COSV99675635; called by muse, mutect2, varscan2
- SOX4 | c.1103C>A p.S368* | Nonsense Mutation (SNP) | VAF 57/203 reads (28%) | catalogued as COSV55193252; called by muse, varscan2
- LDHAL6A | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCOA6 | c.5549G>T p.G1850V | Missense Mutation (SNP) | VAF 133/293 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCOA6 | c.5548G>A p.G1850R | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2A7 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SOX4 | c.637_641dup p.H215Nfs*81 | Frame Shift Ins (INS) | VAF 61/142 reads (43%) | called by mutect2, pindel, varscan2
- SOX4 | c.1175C>A p.S392* | Nonsense Mutation (SNP) | VAF 32/224 reads (14%) | called by muse, varscan2
- AMPD2 | c.1962C>T p.S654= | Silent (SNP) | VAF 105/254 reads (41%) | called by muse, mutect2, varscan2
- ATF7IP | c.3510C>T p.R1170= | Silent (SNP) | VAF 199/426 reads (47%) | catalogued as rs369961485; called by muse, mutect2, varscan2
- ESR2 | c.1335C>A p.G445= | Silent (SNP) | VAF 136/436 reads (31%) | called by muse, mutect2, varscan2
- SP140L | c.1233C>T p.D411= | Silent (SNP) | VAF 103/231 reads (45%) | catalogued as rs760421071, COSV54745025; called by muse, mutect2, varscan2
- ZBTB44 | c.1614C>T p.T538= | Silent (SNP) | VAF 80/185 reads (43%) | catalogued as rs769074062; called by muse, mutect2, varscan2
- DGKZ | c.2088+20C>T | Intron (SNP) | VAF 67/209 reads (32%) | catalogued as rs754390415; called by muse, mutect2, varscan2
- DIABLO | c.-37+1410C>T | Intron (SNP) | VAF 189/403 reads (47%) | called by muse, mutect2, varscan2
- SLC22A11 | c.-16C>T | 5'UTR (SNP) | VAF 93/173 reads (54%) | catalogued as rs201316940, COSV100102038, COSV100102709; called by muse, mutect2, varscan2
- YWHAG | c.*2001T>G | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, varscan2
